Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YH-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED] Accession #: [REDACTED]
Med. Rec. #: [REDACTED] Client: [REDACTED]
DOB: [REDACTED] Location: [REDACTED]
Gender: F Taken: [REDACTED]
Physician(s): [REDACTED] Received: [REDACTED]
cc: [REDACTED] Reported: 1

History/Clinical Dx: Leiomyomata uteri

Postoperative Dx: Pending pathology examination

1cD-0-3 Not applicable.
Normal path from a non-cancer patient.
for 11/11/11

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

DIAGNOSIS:

Cervix: Nabothian cyst
Endometrium: 1. Endometrial polyp
2. Secretory endometrium
Myometrium: Adenomyosis
Bilateral ovaries: 1. Corpus luteum cyst
2. Follicular cyst
Bilateral fallopian tubes: No significant histopathology

Gross Description

Received in formalin labeled "uterus, bilateral ovaries and fallopian tubes" is a uterus with detached cervix and bilateral adnexa weighing 1183 grams, the uterus measures 18.0 x 15.0 x 9.0 cm, detached cervix measures 6.0 x 5.0 x 1.5 cm. The ovary measures 4.5 x 1.5 x 1.5 cm and the attached fallopian tube measures 3.0 cm in length, which is interrupted by ligation. The contralateral ovary measures 3.5 x 2.5 x 1.5 cm with attached fallopian tube that measures 3.0 cm in length x 0.5 cm in diameter that is interrupted by ligation, inked red. The uterus is previously opened anteriorly and the serosal surface is irregular with multiple bulges. The endometrium is pink measuring 0.9 cm in thickness. The cavity is partly distorted by compression of the myometrial mass. The myometrium appears trabeculated mostly occupying the entire fundus towards the lower uterine segment, there is a nodular whorled mass at the lower uterine segment measuring 2.5 x 2.5 x 1.0 cm. The myometrial thickness measures 6.5 cm. The endocervical canal appears unremarkable. The exocervix is pink-tan and smooth. The inked adnexa, portion of the ovary has been removed. The cut surface of the ovary reveals a 2.0 x 1.0 x 0.8 cm hemorrhagic cyst containing fleshy red material which is adherent to the cyst wall. The remaining parenchyma of the ovary is unremarkable. The fallopian tube that is attached is previously ligated and shows few scattered paratubal cyst, largest of which measures up to 0.4 cm. The adnexal which is inked red shows a portion of the ovarian parenchyma removed. The cut surfaces reveals a cystic structure measuring 1.5 x 1.5 x 1.0 cm. The inner wall appears smooth and glistening and the remaining ovarian parenchyma is unremarkable. The attached fallopian tube is unremarkable. Representative sections are submitted as follows:

KEY TO CASSETTES:

1-2 - Cervix
3 - Lower uterine segment

Regulatory Statement

The laboratory is not responsible for the use of the report for purposes not intended by the laboratory. This report was developed and its performance characteristics determined by the laboratory and approved by the U.S. Food and Drug Administration. The FDA has determined that this report is not for clinical purposes. It should not be used for clinical purposes. The laboratory is not responsible for the use of the report for purposes not intended by the laboratory. This laboratory is not responsible for the use of the report for purposes not intended by the laboratory. This laboratory is not responsible for the use of the report for purposes not intended by the laboratory.

[page 2 of 2]
Surgical Pathology Report

4-5 - Endo/myometrium
6 - Mass
7-10 - Myometrium with (in cassette 10 with serosa)
11-12 - Bilateral adnexa

Microscopic Description

The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 0b71c045-a5b3-4506-b670-79c1e487ff4d (TCGA-FL-A1YH.F49FD879-727C-4F5E-B4B8-6FE59B4C05FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).